Somatic mutation profile of tumor specimen TARGET-40-NAAWHG-01A (aliquot TARGET-40-NAAWHG-01A-01D) from TARGET case TARGET-40-NAAWHG, project TARGET-OS (Osteosarcoma). Sex at birth: female; Primary diagnosis: Osteosarcoma, NOS; Age at diagnosis: 18.0 years (6,570 days).
Specimen TARGET-40-NAAWHG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d52f15f-3aa2-4994-a7c5-ceee8f12883f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAWHG-10A (Blood Derived Normal), aliquot TARGET-40-NAAWHG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/222e32d8-9caa-4d65-a73d-caf8c5a42e94

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 27/94 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CNTN3 | c.2300G>A p.S767N | Missense Mutation (SNP) | VAF 112/345 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV55163781; called by muse, mutect2, varscan2
